CGCI case BLGSP-71-23-00448 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f8af2e48-1ff0-48f5-be58-aceea4b6f0d3

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 51 years.

Diagnoses (1)
1. Primary of the hematopoietic system (histology not recorded by GDC). Age at diagnosis: 51.7 years (18,896 days); Year of diagnosis: 2010; Method of diagnosis: Incisional Biopsy.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00448-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-23-00448-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00448-01-BCL2: Tissue microarray coordinates: E2,B3,D5.
  Slide BLGSP-71-23-00448-01-CD10: Tissue microarray coordinates: E2,B3,D5.
  Slide BLGSP-71-23-00448-01-Ki67: Tissue microarray coordinates: E2,B3,D5.
  Slide BLGSP-71-23-00448-01-HE-1: Tissue microarray coordinates: E2,B3,D5.
  Slide BLGSP-71-23-00448-01-BCL6: Tissue microarray coordinates: E2,B3,D5.
  Slide BLGSP-71-23-00448-01-CD20: Tissue microarray coordinates: E2,B3,D5.
  Slide BLGSP-71-23-00448-01-CD3: Tissue microarray coordinates: E2,B3,D5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: Yes.
